CGCI case HTMCP-01-16-00767 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0a61b3a8-45bd-46fe-a095-ba27795e401d

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. EBV positive diffuse large B-cell lymphoma of the elderly: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: primary; Age at diagnosis: 46.1 years (16,830 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; Ann Arbor clinical stage: Stage II; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,031 days (8.3 years); Ann Arbor extranodal involvement: No; Max tumor bulk site: Cervical lymph nodes.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 5 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Surgery, NOS, for recurrent disease.

Follow-up (6 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 230 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 230 days.
- Days to follow up: 1,034 days (2.8 years); Disease response: With Tumor.
- Days to follow up: 2,779 days (7.6 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Positive.
- Days to follow up: 3,031 days (8.3 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Positive.
- Follow-up contact recording only the day: day -3,617.

Molecular and laboratory tests
- ALK (IHC): Normal.
- ALK: Negative.
- BCL2 (IHC): Negative.
- BCL2 (IHC): Normal.
- BCL2: Negative.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- BCL6 (IHC): Normal.
- BCL6: Negative; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD10: Negative; Specialized molecular test: CD10 > 30%.
- CD138: Negative.
- CD20 (IHC): Positive.
- CD20: Negative.
- CD3 (IHC): Negative.
- CD30: Positive.
- CD5: Negative.
- CD79A (IHC): Positive.
- CD79A: Positive.
- IGH (PCR): Abnormal, NOS; Clonality: Clonal.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- IRF4: Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- PAX5: Positive.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Test: Negative; Specialized molecular test: HHV8.
- Epstein-Barr Virus (ISH): Positive.
- Lactate Dehydrogenase 597 [Blood test normal range upper: 618].

Other clinical attributes
- Day -3,617: Risk factors: HIV/AIDS.
- Day -3,617: Comorbidities: HIV/AIDS.
- Day 0: Immunosuppressive treatment type: Methotrexate; Risk factor treatment: Yes.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Weight: 74.4 kg; Height: 172.72 cm; BMI: 24.9; CD4 count: 375; Haart treatment indicator: Yes.
- Day 0: Risk factors: Dermatomyosis.
- Day 0: Comorbidities: Dermatomyosis.
- Day 1,034: Nadir CD4 count: 110.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 1.8; Tobacco smoking quit year: 1997.

Biospecimens (3 samples)
- Sample HTMCP-01-16-00767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-16-00767-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-16-00767-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: EBV positive DLBCL of the elderly; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Tobacco smoking age started: 19; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- History of disease: Year of HIV diagnosis: 2002; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact; History immunological disease other: dermatomyositis.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: No Known Extranodal Involvement.
- Primary pathology: Tumor resected max dimension: 5.0; Days from index date to tumor sample procurement: -16; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Other pos node location: cervical; Bone marrow sample histology: Discordant Histology.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Tests performed: LDH level: 597; B cell genotype method: IgH PCR; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD138.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD79a.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: PAX5.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunophenotypic analysis tested: HHV8.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunophenotypic analysis tested: CD30.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunophenotypic analysis tested: ALK.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL6.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: ALK.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-16-00767-01A-01E-14372:
- % tumour top: 60
- % tumour bottom: 60

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-16-00767-01A-01S-14372:
- % tumour top: 60
- % tumour bottom: 60
